Gene-level copy-number profile of tumor specimen C3N-02067-01 (profiled together with C3N-02067-02) from CPTAC case C3N-02067, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 37.6 years (13,731 days).
Specimen C3N-02067-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e974bd8e-e4a3-4040-b14f-941729553863.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02067-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/0ba2a0a9-5ffb-43da-8d10-e1d0d63854b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,927; copy number 2: 35,071; copy number 3: 13,373; copy number 4: 6,024; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:73,740,541–73,743,716, 1 gene: CXCL8.
- chr6:31,441,667–31,463,336, 2 genes (within-gene range 0–2): LINC01149, AL645933.1.
- chr15:21,293,653–21,295,201, 1 gene: AC068446.1.
- chr15:21,980,277–21,981,245, 1 gene: OR11J6P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,332,892–54,355,954, 1 gene, copy number 5: LINC02283.

Autosomal genes at a single copy (total copy number 1): 3,927. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
